Somatic mutation profile of tumor specimen 0DCM1L from CCDI case PBBLSE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 8.0 years (2,919 days).
Specimen 0DCM1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 461718df-7150-4c97-8fa9-15b6e8e3fd41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCM18 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3354a221-9631-4c69-afe8-ce2f5c75282f

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 3, 5'UTR 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD16 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 74/838 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs769336919, COSV99584985; called by muse, mutect2
- C14orf28 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 61/486 reads (13%) | catalogued as rs749310294, COSV57333841; called by muse, mutect2, varscan2
- GRID2 | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 105/1019 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757011419; called by muse, mutect2, varscan2
- PDHA1 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 64/990 reads (6%) | catalogued as CM084910, CM920573, COSV100134109; called by muse, mutect2
- PDILT | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 99/776 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100199885; called by muse, mutect2
- SLC6A8 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 187/496 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.6); catalogued as rs1557045723, COSV53471836; called by muse, mutect2, varscan2
- UTRN | c.8210C>A p.A2737E | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV100838530; called by muse, mutect2, varscan2
- ADAMTS20 | c.1511A>C p.N504T | Missense Mutation (SNP) | VAF 86/1078 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.159); called by muse, mutect2
- CALCRL | c.1095T>A p.Y365* | Nonsense Mutation (SNP) | VAF 137/1367 reads (10%) | called by muse, mutect2, varscan2
- DIP2C | c.3026A>G p.K1009R | Missense Mutation (SNP) | VAF 393/995 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GGT2 | c.1402G>C p.V468L | Missense Mutation (SNP) | VAF 22/888 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2
- GPR45 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL17D | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.265); called by muse, mutect2
- KIF1A | c.4939C>T p.P1647S (on ENST00000320389 / NM_001379639.1; = p.P1639S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MTPAP | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 278/804 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- RNF8 | c.516G>T p.L172F | Missense Mutation (SNP) | VAF 118/1229 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.125); called by muse, mutect2
- SLC27A6 | c.1791G>C p.L597F | Missense Mutation (SNP) | VAF 553/1408 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- THSD7B | c.1500C>A p.N500K | Missense Mutation (SNP) | VAF 520/1212 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TRPC4 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 125/1012 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP29 | c.2645A>G p.Y882C | Missense Mutation (SNP) | VAF 163/309 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCP | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 147/1234 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- WDR18 | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ZNF311 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 86/681 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF850 | c.3061C>G p.P1021A | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2
- IQCE | c.2058G>A p.P686= | Silent (SNP) | VAF 348/871 reads (40%) | catalogued as rs571456409; called by muse, mutect2, varscan2
- ITIH6 | c.2760C>T p.T920= | Silent (SNP) | VAF 24/870 reads (3%) | catalogued as COSV99512757; called by muse, mutect2
- MAGI1 | c.502T>C p.L168= | Silent (SNP) | VAF 442/1073 reads (41%) | called by muse, mutect2, varscan2
- MEP1B | c.1860T>C p.T620= | Silent (SNP) | VAF 54/1518 reads (4%) | catalogued as rs1324580051; called by muse, mutect2
- MFSD5 | c.393A>G p.L131= | Silent (SNP) | VAF 263/572 reads (46%) | called by muse, mutect2, varscan2
- NOTCH4 | c.5337G>C p.A1779= | Silent (SNP) | VAF 72/846 reads (9%) | called by muse, mutect2
- PCDHGA5 | c.471G>A p.A157= | Silent (SNP) | VAF 90/970 reads (9%) | catalogued as COSV53915698; called by muse, mutect2
- ZNF462 | c.6417A>G p.E2139= | Silent (SNP) | VAF 108/1225 reads (9%) | called by muse, mutect2
- ANKRD54 | chr22:37848437 C>A | 5'Flank (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- DDHD1 | c.1176-23T>A | Intron (SNP) | VAF 43/218 reads (20%) | called by muse, mutect2, varscan2
- MEGF10 | c.1dup | 5'UTR (INS) | VAF 88/798 reads (11%) | catalogued as rs772563644; called by mutect2, varscan2
- NME7 | c.-87G>T | 5'UTR (SNP) | VAF 26/510 reads (5%) | catalogued as rs1344235928; called by muse, mutect2
